TCGA case TCGA-61-2008 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ac45a71-c463-4f0f-b030-58c475a34418

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 40.5 years (14,791 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 932 days (2.6 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: No macroscopic disease; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 149 days; Number of cycles: 6; Treatment dose: 3,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 149 days; Number of cycles: 6; Treatment dose: 690 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 861 days (2.4 years); Days to treatment end: 979 days (2.7 years); Number of cycles: 6; Treatment dose: 702 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 861 days (2.4 years); Days to treatment end: 979 days (2.7 years); Number of cycles: 6; Treatment dose: 1,260 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 861 days (2.4 years); Days to treatment end: 979 days (2.7 years); Number of cycles: 6; Treatment dose: 372 mg; Route of administration: Intraperitoneal.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 42.7 years (15,609 days); Days to diagnosis: 818 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 828 days (2.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 818 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 818 days (2.2 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 932 days (2.6 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-2008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-61-2008-01A-02-BS2: Section location: Bottom; Percent tumor cells: 69; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 30.
  Slide TCGA-61-2008-01A-01-BS1: Section location: Top; Percent tumor cells: 69; Percent tumor nuclei: 70; Percent normal cells: 1; Percent necrosis: 1; Percent stromal cells: 29.
- Sample TCGA-61-2008-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 2; Intermediate dimension: 1.5; Shortest dimension: 0.3.
  Slide TCGA-61-2008-02A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
  Slide TCGA-61-2008-02A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-61-2008-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IP.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3, Route of administrations: Route of administration: IP; Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 932 days; disease-specific survival: no event (censored), 932 days; disease-free interval: event (new tumor event after initially disease-free), 818 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 818 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-61-2008-01A-02D-0663-01): tumor purity 0.78, ploidy 3.13, whole-genome doublings 1.
